Somatic mutation profile of tumor specimen MP2PRT-PASWGB-TMP1-A (aliquot MP2PRT-PASWGB-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASWGB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.7 years (3,193 days).
Specimen MP2PRT-PASWGB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2163c68a-c5cc-47a6-a76a-0196830d8f65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASWGB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASWGB-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d005f17-e863-47ce-a50f-9a680a658bbd

The open-access MAF lists 45 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 10, Nonsense Mutation 3, In Frame Del 1, Intron 1, 5'Flank 1, Splice Region 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PKP2 | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 25/378 reads (7%) | catalogued as rs372827156, CM060431; ClinVar: pathogenic; called by muse, mutect2
- AATK | c.1502G>A p.R501H (on ENST00000326724 / NM_001080395.3; = p.R398H on NM_004920.2) | Missense Mutation (SNP) | VAF 26/988 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as rs1368418565, COSV104399763; called by muse, mutect2
- ADAMTS9 | c.4781G>A p.R1594H | Missense Mutation (SNP) | VAF 88/468 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs760094936, COSV55775231; called by muse, mutect2, varscan2
- C8orf34 | c.1326C>T p.F442= | Splice Region (SNP) | VAF 16/202 reads (8%) | catalogued as rs201463505, COSV57396967; called by muse, mutect2
- CACNG5 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 74/513 reads (14%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.679); catalogued as rs763448235, COSV50055506; called by muse, mutect2, varscan2
- EPHA10 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 108/325 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.613); catalogued as rs1469602008; called by muse, mutect2, varscan2
- ESRRB | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 111/746 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs757736226, COSV55062957, COSV99834957; called by muse, mutect2, varscan2
- FAT4 | c.5401C>T p.R1801W | Missense Mutation (SNP) | VAF 121/445 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs201887525; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLYR1 | c.1072G>A p.V358M | Missense Mutation (SNP) | VAF 148/389 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs372798176, COSV99062353; called by muse, mutect2, varscan2
- HUWE1 | c.8945G>A p.R2982Q | Missense Mutation (SNP) | VAF 174/381 reads (46%) | SIFT tolerated (0.75); PolyPhen benign (0.109); catalogued as rs782720863, COSV104394295; called by muse, mutect2, varscan2
- ITPKB | c.2473C>T p.R825W | Missense Mutation (SNP) | VAF 63/374 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs778973917, COSV55263643; called by muse, mutect2, varscan2
- MROH7 | c.2827C>T p.R943C | Missense Mutation (SNP) | VAF 97/263 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); catalogued as rs771841626; called by muse, mutect2, varscan2
- NKX2-6 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 39/561 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.052); catalogued as COSV61493624; called by muse, mutect2
- OR5K3 | c.160C>A p.R54S | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs150899692, COSV67350205; called by muse, mutect2, varscan2
- PEG3 | c.3694C>T p.Q1232* | Nonsense Mutation (SNP) | VAF 114/323 reads (35%) | catalogued as COSV55645903; called by muse, mutect2, varscan2
- POF1B | c.91C>A p.H31N | Missense Mutation (SNP) | VAF 26/472 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as COSV53130706; called by muse, mutect2
- PROKR2 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 41/311 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs1235576605, CM163185; called by muse, mutect2, varscan2
- PTPRZ1 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 15/319 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.125); catalogued as rs1469276203, COSV66432630; called by muse, mutect2
- RPL11 | c.100C>T p.R34* (on ENST00000374550 / NM_001199802.1; = p.R35* on NM_000975.5) | Nonsense Mutation (SNP) | VAF 59/311 reads (19%) | catalogued as COSV65778956; called by muse, mutect2, varscan2
- RYR3 | c.5356G>A p.G1786S | Missense Mutation (SNP) | VAF 38/414 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs759581452; called by muse, mutect2
- SCN3A | c.4898G>A p.R1633H | Missense Mutation (SNP) | VAF 85/342 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51801775; called by muse, mutect2, varscan2
- STARD13 | c.2132G>A p.R711H (on ENST00000336934 / NM_001243476.3; = p.R593H on NM_052851.3) | Missense Mutation (SNP) | VAF 83/230 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781620333; called by muse, mutect2, varscan2
- SYT3 | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 26/502 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs200430574; called by muse, mutect2
- TP53 | c.695_696dup p.H233Sfs*15 | Frame Shift Ins (INS) | VAF 18/194 reads (9%) | catalogued as COSV52823085; called by mutect2, pindel
- C11orf97 | c.251-1G>C p.X84_splice | Splice Site (SNP) | VAF 20/154 reads (13%) | called by muse, varscan2
- DCAF8L1 | c.1375T>G p.C459G | Missense Mutation (SNP) | VAF 123/290 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EXOC3L1 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 145/412 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FOXE3 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 29/544 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.074); called by muse, mutect2
- IGKV2-30 | c.355_357del p.W119del | In Frame Del (DEL) | VAF 28/56 reads (50%) | called by pindel*, varscan2
- IGSF23 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 15/442 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- PKDREJ | c.1094A>G p.D365G | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); called by muse, mutect2
- SCP2 | c.1351T>C p.F451L | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- TRIM67 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 144/778 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUSP21 | c.15G>A p.A5= | Silent (SNP) | VAF 66/319 reads (21%) | called by muse, mutect2, varscan2
- EEF1A2 | c.45C>T p.H15= | Silent (SNP) | VAF 91/285 reads (32%) | catalogued as rs546748631, COSV99419134; called by muse, mutect2, varscan2
- FOXN3 | c.1188C>T p.D396= (on ENST00000261302; = p.D374= on NM_005197.4) | Silent (SNP) | VAF 82/651 reads (13%) | catalogued as rs143673672; called by muse, varscan2
- KCNMA1 | c.3210G>A p.P1070= (on ENST00000286628 / NM_001161352.2; = p.P1012= on NM_002247.4) | Silent (SNP) | VAF 51/382 reads (13%) | catalogued as rs752923387, COSV54242231; called by muse, mutect2, varscan2
- LAG3 | c.1008T>C p.H336= | Silent (SNP) | VAF 26/362 reads (7%) | catalogued as rs759009654; called by muse, mutect2
- MICOS13 | c.345G>A p.A115= | Silent (SNP) | VAF 57/313 reads (18%) | catalogued as rs777798994, COSV56797518; called by muse, mutect2, varscan2
- PKD1 | c.3762G>A p.S1254= | Silent (SNP) | VAF 105/499 reads (21%) | catalogued as rs762657963; called by muse, mutect2, varscan2
- RYR3 | c.12396C>T p.D4132= (on ENST00000389232; = p.D4133= on NM_001036.6) | Silent (SNP) | VAF 56/270 reads (21%) | catalogued as rs563141444, COSV66782596; called by muse, mutect2, varscan2
- SCARA5 | c.534C>T p.S178= | Silent (SNP) | VAF 52/692 reads (8%) | catalogued as rs779423568; called by muse, mutect2
- SOD3 | c.216C>T p.D72= | Silent (SNP) | VAF 60/911 reads (7%) | called by muse, mutect2
- QKI | c.935-760C>T | Intron (SNP) | VAF 15/191 reads (8%) | catalogued as rs1237382034, COSV51691523; called by muse, mutect2
- TRGJP | chr7:38276318 ins CG | 5'Flank (INS) | VAF 53/91 reads (58%) | called by mutect2, pindel, varscan2
